Somatic mutation profile of tumor specimen HCM-BROD-1123-C71-02A (aliquot HCM-BROD-1123-C71-02A-11D-A881-36) from HCMI case HCM-BROD-1123-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.2 years (17,954 days).
Specimen HCM-BROD-1123-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f54e40e-19d2-4577-aab2-82df3ee14046.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1123-C71-10A (Blood Derived Normal), aliquot HCM-BROD-1123-C71-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c37777c2-f9af-4a32-914a-0bb260323003

The open-access MAF lists 928 somatic variants for this specimen: 610 protein-altering or splice-affecting, 290 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 531, Silent 290, Nonsense Mutation 27, Splice Site 23, Splice Region 20, Intron 15, Frame Shift Del 8, 3'UTR 7, 3'Flank 2, 5'UTR 2, RNA 1, 5'Flank 1.

Variants (750 of 928; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPH2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 19/451 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs1555988417; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.1393-1G>A p.X465_splice | Splice Site (SNP) | VAF 10/173 reads (6%) | catalogued as rs1131691131, COSV62193333, COSV62199307; ClinVar: likely pathogenic; called by muse, mutect2
- NF1 | c.1721+1G>A p.X574_splice | Splice Site (SNP) | VAF 26/344 reads (8%) | catalogued as rs1131691096, CS086408, CS1311510, CS1311511, COSV100645920; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 44/750 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2
- ABCG5 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 50/568 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV53213532; called by muse, mutect2
- ACSL1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99860969; called by muse, mutect2
- ADGRE2 | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.275); catalogued as COSV100216302; called by muse, mutect2, varscan2
- ADGRF3 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as rs990883055; called by muse, mutect2
- AHNAK2 | c.6410G>A p.G2137E | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1240199856; called by muse, varscan2
- AKAP12 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 19/716 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1321456441; called by muse, mutect2
- AKAP8 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 80/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54104898; called by muse, mutect2, varscan2
- ALDH3B2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 56/682 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV62427801; called by muse, mutect2
- ALLC | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757104090, COSV52993453; called by muse, mutect2
- ALPK1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 47/545 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771984525, COSV51582524; called by muse, mutect2
- ALPK3 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 77/738 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); catalogued as rs1267089454; called by muse, mutect2, varscan2
- ALPK3 | c.4771G>A p.G1591R | Missense Mutation (SNP) | VAF 36/517 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291198969; called by muse, mutect2
- AMH | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 30/996 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs1325512870; called by muse, mutect2
- ANKRD34B | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 40/572 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV58613820; called by muse, mutect2
- ARAP3 | c.4027C>T p.R1343C | Missense Mutation (SNP) | VAF 92/479 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs763833196; called by muse, mutect2, varscan2
- ARID1A | c.4493G>A p.W1498* | Nonsense Mutation (SNP) | VAF 54/686 reads (8%) | catalogued as COSV61378299; called by muse, mutect2
- ATAD2B | c.3640G>A p.D1214N | Missense Mutation (SNP) | VAF 23/464 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs1431341614; called by muse, mutect2
- ATP13A2 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 58/862 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs779347442; ClinVar: uncertain significance; called by muse, mutect2
- ATP8A2 | c.1263G>A p.Q421= | Splice Region (SNP) | VAF 29/356 reads (8%) | catalogued as COSV54957561; called by muse, mutect2
- BCL9L | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 34/773 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52689660; called by muse, mutect2
- BTBD17 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 60/840 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV64730970; called by muse, mutect2
- BX248415.1 | n.425G>A | Splice Region (SNP) | VAF 49/330 reads (15%) | catalogued as rs757684781; called by muse, mutect2, varscan2
- C15orf39 | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 32/604 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.099); catalogued as COSV100641343; called by muse, mutect2
- CADM3 | c.662G>A p.R221K (on ENST00000368125 / NM_001127173.3; = p.R255K on NM_021189.5) | Missense Mutation (SNP) | VAF 36/514 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV100930399, COSV63684559, COSV63687767; called by muse, mutect2
- CAPN15 | c.2969A>T p.E990V | Missense Mutation (SNP) | VAF 132/696 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769060825; called by muse, mutect2, varscan2
- CARF | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs377372943; called by muse, mutect2, varscan2
- CARMIL2 | c.1686C>T p.C562= | Splice Region (SNP) | VAF 18/521 reads (3%) | catalogued as COSV99075810; called by muse, mutect2
- CDH19 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 109/560 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs141432968, COSV50956344; called by muse, mutect2, varscan2
- CDK4 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV56983667; called by muse, mutect2
- CEP85 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 40/730 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.431); catalogued as rs567012962, COSV99432669; called by muse, mutect2
- CFAP54 | c.4106G>A p.R1369K | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.807); catalogued as COSV101598467; called by muse, mutect2, varscan2
- CMBL | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.484); catalogued as rs1021727547; called by muse, mutect2
- CNGB1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 56/504 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as rs765835118, COSV51900464; called by muse, varscan2
- COIL | c.1440+1G>A p.X480_splice | Splice Site (SNP) | VAF 34/399 reads (9%) | catalogued as rs755263920; called by muse, mutect2
- COL1A1 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 61/635 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV56809247; called by muse, mutect2
- CRISP3 | c.614+1G>A p.X205_splice (on ENST00000371159 / NM_001368123.1; = p.X187_splice on NM_006061.4) | Splice Site (SNP) | VAF 39/237 reads (16%) | catalogued as rs762333204, COSV53819771, COSV53821819; called by muse, mutect2, varscan2
- CRYGC | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.134); catalogued as COSV56408980; called by muse, mutect2
- CRYGN | c.273C>T p.H91= | Splice Region (SNP) | VAF 30/328 reads (9%) | catalogued as rs146240466; called by muse, mutect2
- CTNND2 | c.3391C>T p.P1131S | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV58885310; called by muse, mutect2
- DAAM1 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 60/651 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs1283867125; called by muse, mutect2
- DAPL1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1198558136; called by muse, mutect2
- DHX16 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 78/852 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs1008551246; called by muse, mutect2
- DHX30 | c.2207C>T p.T736I (on ENST00000445061 / NM_138615.3; = p.T697I on NM_014966.3) | Missense Mutation (SNP) | VAF 25/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99276289; called by muse, mutect2
- DIABLO | c.424G>A p.E142K (on ENST00000443649 / NM_001278303.1; = p.E215K on NM_019887.6) | Missense Mutation (SNP) | VAF 62/679 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99928226; called by muse, mutect2
- DSC1 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57151251; called by muse, mutect2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- EFTUD2 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763935473, COSV99493825; called by muse, mutect2, varscan2
- EGFR | c.827A>T p.Q276L | Missense Mutation (SNP) | VAF 135/779 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99294781; called by muse, mutect2, varscan2
- EGLN2 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 69/685 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs776147138, COSV58280342; called by muse, mutect2, varscan2
- EML5 | c.5551G>A p.V1851M (on ENST00000380664; = p.V1859M on NM_183387.3) | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.886); catalogued as rs1388081421; called by muse, mutect2
- ENO3 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1472421155; called by muse, mutect2
- EP300 | c.5762C>T p.P1921L | Missense Mutation (SNP) | VAF 46/874 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV99609698; called by muse, mutect2
- EVPLL | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 75/477 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs755615782; called by muse, mutect2, varscan2
- EXOC2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 39/406 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs1480236460; called by muse, mutect2, varscan2
- FAAP100 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 50/890 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100585387; called by muse, mutect2
- FAM187B | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 44/668 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV61200983; called by muse, mutect2
- FAT1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 52/664 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101499477, COSV71671689; called by muse, mutect2
- FFAR1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 36/778 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs1486045762; called by muse, mutect2
- FLG2 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 25/554 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV66170213; called by muse, mutect2
- GALM | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 22/566 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV55371227; called by muse, mutect2
- GALNT13 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as rs765871349; called by muse, mutect2, varscan2
- GIMAP4 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 62/714 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV55432742; called by muse, mutect2
- GJA8 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 84/637 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs140686949; called by muse, mutect2, varscan2
- GPATCH2L | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 19/538 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV55048590; called by muse, mutect2
- GPC2 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 58/936 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749967833; called by muse, mutect2
- GRIK3 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 24/471 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66140161; called by muse, mutect2
- GSC2 | c.542G>A p.W181* | Nonsense Mutation (SNP) | VAF 74/788 reads (9%) | catalogued as rs1555917841; called by muse, mutect2
- GTPBP6 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 38/724 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as rs757364188; called by muse, mutect2
- H2BC12 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 50/1068 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63617488; called by muse, mutect2
- HELT | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 71/970 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs777810182; called by muse, mutect2
- HHIP | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 19/532 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV99667353; called by muse, mutect2
- HIF1A | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 75/460 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1566573924; called by muse, mutect2, varscan2
- HIVEP2 | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 56/417 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs766328392; called by muse, mutect2, varscan2
- HNRNPM | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as rs774224489; called by muse, mutect2, varscan2
- HRH1 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 27/524 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV67955269; called by muse, mutect2
- IFIT2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV51079198; called by muse, mutect2, varscan2
- IGF2R | c.6298G>A p.V2100M | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs758814989; called by muse, mutect2, varscan2
- IGHV1-2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 79/503 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as rs781877284; called by muse, mutect2, varscan2
- IGHV3-49 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs781835190; called by muse, mutect2
- IGKV1D-8 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 41/519 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs372314910; called by muse, mutect2
- IGSF22 | c.2242G>A p.V748M (on ENST00000319338; = p.V849M on NM_173588.4) | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1251348967; called by muse, mutect2
- IL17RC | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 38/521 reads (7%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV55967586; called by muse, mutect2
- INHBA | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 128/783 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV54225839; called by muse, mutect2, varscan2
- INO80 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 35/724 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV62739840; called by muse, mutect2
- INTS7 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs1487422106; called by muse, mutect2
- IPP | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 20/479 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63431870; called by muse, mutect2
- IRF7 | c.719G>A p.G240D (on ENST00000397566; = p.G227D on NM_001572.5) | Missense Mutation (SNP) | VAF 33/557 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1162516129; called by muse, mutect2
- ITK | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 44/572 reads (8%) | catalogued as rs776317714; called by muse, mutect2
- KEL | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 51/892 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV100786939; called by muse, mutect2
- KLF1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 64/1053 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1188078419; called by muse, mutect2
- KRT77 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 80/511 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs200230736; called by muse, mutect2, varscan2
- LEXM | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 127/629 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs747586144, COSV64023909; called by muse, mutect2, varscan2
- LHFPL3 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 19/394 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs1219946539; called by muse, mutect2
- LILRA2 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 88/611 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs769487000, COSV52189795; called by muse, mutect2, varscan2
- LRP2 | c.13877C>T p.P4626L | Missense Mutation (SNP) | VAF 30/655 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV55564357; called by muse, mutect2
- LRRC7 | c.2394G>A p.M798I (on ENST00000651989 / NM_001370785.2; = p.M765I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/626 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs568596228; called by muse, mutect2
- MACF1 | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 16/264 reads (6%) | catalogued as COSV100484359; called by muse, mutect2
- MALSU1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 29/704 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs913939410; called by muse, mutect2
- MAML1 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 23/602 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.4); catalogued as rs1198260485; called by muse, mutect2
- MAP2 | c.5212G>A p.A1738T | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52284292; called by muse, mutect2
- MAP4 | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 21/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99274814; called by muse, mutect2
- MCM4 | c.326G>A p.G109D | Missense Mutation (SNP) | VAF 45/600 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs749518983; called by muse, mutect2
- MDGA1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 79/614 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs1426870659; called by muse, mutect2, varscan2
- MGAT3 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 102/631 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.769); catalogued as COSV100361953; called by muse, mutect2, varscan2
- MIDEAS | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 60/740 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs1005226104; called by muse, mutect2
- MMP13 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs372747673; called by muse, mutect2, varscan2
- MMP20 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 20/483 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322568092, COSV52774225; called by muse, mutect2
- MMP9 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 61/506 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1343892427, COSV63434419; called by muse, mutect2, varscan2
- MMS19 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1264092565; called by muse, mutect2
- MORC1 | c.1767+1G>T p.X589_splice | Splice Site (SNP) | VAF 51/286 reads (18%) | catalogued as rs774023589, COSV51713802; called by muse, mutect2, varscan2
- MUC17 | c.4318G>A p.A1440T | Missense Mutation (SNP) | VAF 82/501 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs796436659; called by muse, mutect2, varscan2
- MUC17 | c.9500C>T p.T3167I | Missense Mutation (SNP) | VAF 56/732 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs377434098; called by muse, mutect2
- MUC2 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 14/500 reads (3%) | SIFT deleterious (0); catalogued as rs763898700; called by muse, mutect2
- MUC22 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 55/646 reads (9%) | SIFT deleterious, low confidence (0.01); catalogued as rs1019381354; called by muse, mutect2
- NBAS | c.5849C>T p.T1950I | Missense Mutation (SNP) | VAF 50/656 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV55713076; called by muse, mutect2
- NCKAP5 | c.5675G>A p.R1892K | Missense Mutation (SNP) | VAF 21/546 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV58471279; called by muse, mutect2
- NEXMIF | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV50084166; called by muse, mutect2, varscan2
- NLGN3 | c.2137G>A p.A713T (on ENST00000358741 / NM_181303.2; = p.A693T on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62445021; called by muse, mutect2
- NPTX1 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 17/429 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60774622; called by muse, mutect2
- NR2F2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 60/762 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1193561443; called by muse, mutect2
- NUTM2B | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 54/1175 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1310753146; called by muse, mutect2
- NXPE4 | c.1580C>T p.P527L (on ENST00000375478 / NM_001077639.2; = p.P243L on NM_017678.3) | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV64943405; called by muse, mutect2
- OBSCN | c.9791C>T p.S3264F | Missense Mutation (SNP) | VAF 29/511 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV52772606; called by muse, mutect2
- OR10G8 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.35); catalogued as COSV70908638; called by muse, mutect2, varscan2
- OR2T3 | c.175del p.R59Afs*23 | Frame Shift Del (DEL) | VAF 32/234 reads (14%) | catalogued as COSV62082821; called by mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 97/617 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- OR4A5 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV60521730, COSV60523084; called by muse, mutect2
- OR51L1 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58624610; called by muse, mutect2, varscan2
- OR5F1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53545541; called by muse, mutect2
- OSBPL10 | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 72/718 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs779988055; called by muse, mutect2
- PACSIN1 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 21/598 reads (4%) | catalogued as COSV55060759; called by muse, mutect2
- PAN2 | c.2362G>A p.E788K (on ENST00000425394 / NM_001127460.3; = p.E784K on NM_014871.5) | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV57753814; called by muse, mutect2, varscan2
- PCDH17 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 55/565 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1473920111, COSV64975033; called by muse, mutect2, varscan2
- PCDHA5 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 113/838 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs782323770, COSV65356157; called by muse, mutect2, varscan2
- PCDHB7 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 184/5384 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs782388523, COSV50763014; called by muse, mutect2
- PCDHGA7 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 17/547 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.072); catalogued as rs1285071081, COSV99548900; called by muse, mutect2
- PCDHGB1 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 162/835 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54022696; called by muse, mutect2, varscan2
- PCSK5 | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 32/575 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV101377469; called by muse, mutect2
- PDE1C | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 19/505 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58529376; called by muse, mutect2
- PDE4D | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 80/788 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as COSV61457596; called by muse, mutect2
- PDE6B | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 94/511 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs545001524; called by muse, mutect2, varscan2
- PEAR1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 24/554 reads (4%) | catalogued as COSV52770617; called by muse, mutect2
- PEX10 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 52/903 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs375171673; called by muse, mutect2
- PEX12 | c.126+1G>A p.X42_splice | Splice Site (SNP) | VAF 19/184 reads (10%) | catalogued as rs144259891, CS982317; called by muse, mutect2, varscan2
- PIK3CG | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV63249052; called by muse, mutect2
- PIWIL2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs150307872; called by muse, mutect2
- POLR2A | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1435792453; called by muse, mutect2, varscan2
- PPP1R16B | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 46/438 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.171); catalogued as rs753122696; called by muse, mutect2
- PRR19 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 56/652 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs762040582; called by muse, mutect2
- PTGFRN | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1290668315, COSV101277374; called by mutect2, varscan2
- PXDNL | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs756848491, COSV62500182; called by muse, mutect2
- RELN | c.3205A>G p.I1069V | Missense Mutation (SNP) | VAF 31/628 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs963460771; called by muse, mutect2
- RGPD4 | c.5194C>T p.L1732F | Missense Mutation (SNP) | VAF 28/626 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1242564545; called by muse, mutect2
- RGS18 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.067); catalogued as COSV66510161; called by muse, mutect2
- RHEX | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 40/349 reads (11%) | catalogued as rs1190319974; called by muse, mutect2, varscan2
- ROR2 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 34/768 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV65224069; called by muse, mutect2
- RSPH10B2 | c.2510C>T p.P837L | Missense Mutation (SNP) | VAF 40/684 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs759234050; called by muse, mutect2
- RTN4 | c.3398C>T p.A1133V (on ENST00000337526 / NM_020532.5; = p.A140V on NM_007008.3) | Missense Mutation (SNP) | VAF 29/500 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262695675; called by muse, mutect2
- RYR2 | c.6431G>A p.R2144H | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs1243083109, COSV63666184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD9L | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 47/608 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs370922332; called by muse, mutect2
- SAP25 | c.146C>T p.S49L (on ENST00000538735; = p.S147L on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/695 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.363); catalogued as rs1265059172; called by muse, mutect2, varscan2
- SBF1 | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1196565815, COSV62368524; called by muse, mutect2
- SCAF4 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 27/666 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs1410997355; called by muse, mutect2
- SCN4A | c.5185G>A p.V1729M | Missense Mutation (SNP) | VAF 56/682 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as rs749647150; called by muse, mutect2
- SCNN1G | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.749); catalogued as rs1567263665; called by muse, mutect2, varscan2
- SDK1 | c.6553G>A p.V2185I | Missense Mutation (SNP) | VAF 85/1126 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.566); catalogued as COSV67360832; called by muse, mutect2
- SEMA5B | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 80/934 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs907855560; called by muse, mutect2
- SETX | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 26/598 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as CD096492; called by muse, mutect2
- SEZ6 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 19/486 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57977883; called by muse, mutect2
- SLC4A3 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 84/560 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.754); catalogued as COSV56093412; called by muse, mutect2, varscan2
- SLC51A | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 18/491 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1269564751; called by muse, mutect2
- SLC5A9 | c.1495G>A p.V499M | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.903); catalogued as COSV99361552; called by muse, mutect2
- SLC8A2 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 29/763 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV52639020; called by muse, mutect2
- SLC9A4 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 76/808 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181947037; called by muse, mutect2
- SMARCA1 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1180246498; called by muse, mutect2, varscan2
- SNX22 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs752583321; called by muse, mutect2, varscan2
- SOHLH2 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 45/579 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV65901204; called by muse, mutect2
- SPAG16 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV55983413; called by muse, mutect2, varscan2
- SPATA31E1 | c.3838G>A p.G1280S | Missense Mutation (SNP) | VAF 25/683 reads (4%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.638); catalogued as COSV57795189; called by muse, mutect2
- SRY | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as CM023171; called by muse, mutect2, varscan2
- STAB2 | c.6008G>A p.G2003E | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV66345589; called by muse, mutect2
- STK32C | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 53/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53846985; called by muse, mutect2, varscan2
- SZT2 | c.9076T>C p.S3026P (on ENST00000634258 / NM_001365999.1; = p.S2969P on NM_015284.4) | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs749473988; called by muse, mutect2, varscan2
- TAS1R1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 26/750 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1346308659, COSV100062864; called by muse, mutect2
- TASOR2 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 47/392 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.133); catalogued as rs778166755; called by muse, mutect2
- TBCB | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 57/804 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs990286163; called by muse, mutect2
- TET1 | c.3623C>T p.T1208I | Missense Mutation (SNP) | VAF 18/363 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1351417056, COSV65387311; called by muse, mutect2
- TET2 | c.4147A>G p.R1383G | Missense Mutation (SNP) | VAF 76/460 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54404268; called by muse, mutect2, varscan2
- TMEM229A | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 29/967 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV71900381; called by muse, mutect2
- TMEM40 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs776998006; called by muse, mutect2
- TMEM94 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 88/513 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58597863; called by muse, mutect2, varscan2
- TNF | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 114/1272 reads (9%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.974); catalogued as rs1170638621, COSV69305427; called by muse, mutect2
- TOB2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.264); catalogued as rs1453328286; called by muse, mutect2, varscan2
- TREML1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 42/737 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as rs776144903; called by muse, mutect2
- TRIM15 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 44/1170 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1207882226; called by muse, mutect2
- TSC2 | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 49/626 reads (8%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); catalogued as COSV54766652; called by muse, mutect2
- TSPYL5 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 115/581 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.305); catalogued as COSV59071342; called by muse, mutect2, varscan2
- TTC39B | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52608491; called by muse, mutect2
- TTLL12 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 84/1067 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1454195985; called by muse, mutect2
- TTN | c.93115G>A p.A31039T (on ENST00000591111; = p.A23615T on NM_003319.4) | Missense Mutation (SNP) | VAF 27/612 reads (4%) | PolyPhen probably damaging (0.964); catalogued as rs1340922711, COSV100591243; called by muse, mutect2
- TTN | c.52238A>T p.K17413M (on ENST00000591111; = p.K9989M on NM_003319.4) | Missense Mutation (SNP) | VAF 29/691 reads (4%) | PolyPhen probably damaging (0.999); catalogued as COSV59930722; called by muse, mutect2
- TWNK | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 33/600 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs772751928; called by muse, mutect2
- UBE2J1 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 26/708 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1193027961; called by muse, mutect2
- ULBP1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99998337; called by muse, mutect2
- VASN | c.1421C>T p.T474I | Missense Mutation (SNP) | VAF 96/1092 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1473841787; called by muse, mutect2
- VWA7 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 79/978 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs1282878941; called by muse, mutect2
- WDR83OS | c.252C>T p.F84= | Splice Region (SNP) | VAF 13/299 reads (4%) | catalogued as rs1299826627; called by muse, mutect2
- WNT6 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 98/1162 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs779584695; called by muse, mutect2
- XKR4 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 64/734 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs1001362460; called by muse, mutect2
- XPA | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as CX106027, COSV100910309; called by muse, mutect2, varscan2
- ZBED6 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 37/492 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1362549457; called by muse, mutect2
- ZBED9 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 70/640 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV71729456; called by muse, mutect2, varscan2
- ZC3H18 | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 62/776 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as COSV99964442; called by muse, mutect2
- ZC3H6 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 22/558 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs1313780293; called by muse, mutect2
- ZFP82 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 19/559 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67566131; called by muse, mutect2
- ZNF326 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV61036025; called by muse, mutect2, varscan2
- ZNF425 | c.2075G>A p.R692K | Missense Mutation (SNP) | VAF 54/760 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs866264114; called by muse, mutect2
- ZNF721 | c.2245G>A p.V749M (on ENST00000338977; = p.V761M on NM_133474.4) | Missense Mutation (SNP) | VAF 22/429 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV59096486; called by muse, mutect2
- ZNF77 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 35/499 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1163759299; called by muse, mutect2
- ZNF800 | c.1871G>A p.G624E | Missense Mutation (SNP) | VAF 43/538 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014075786, COSV56178052; called by muse, mutect2
- ZSWIM5 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 33/434 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as rs201379465; called by muse, mutect2
- ABCA13 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 25/398 reads (6%) | called by muse, mutect2
- ABCB9 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 26/896 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- ABCC10 | c.1608G>A p.K536= (on ENST00000372530 / NM_001198934.2; = p.K493= on NM_033450.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 12/343 reads (3%) | called by muse, mutect2
- AC005324.2 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 41/420 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AC011005.1 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 49/908 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- ACAN | c.5258C>T p.T1753I | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.974); called by muse, mutect2
- ACO2 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 49/536 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2
- ACTR10 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ADAMTS10 | c.2241C>T p.A747= | Splice Region (SNP) | VAF 28/449 reads (6%) | called by muse, mutect2
- ADAMTS3 | c.3175C>T p.P1059S | Missense Mutation (SNP) | VAF 18/593 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.085); called by muse, mutect2
- ADAMTS4 | c.1818G>A p.W606* | Nonsense Mutation (SNP) | VAF 48/672 reads (7%) | called by muse, mutect2
- ADAMTS4 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 21/635 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADAMTS8 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 58/648 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- ADAMTSL3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGAP2 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 79/838 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, mutect2
- AGR2 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 41/601 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.034); called by muse, mutect2
- AHNAK | c.5668G>A p.G1890S | Missense Mutation (SNP) | VAF 64/802 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- ALDH1L1 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ALMS1 | c.5387C>T p.T1796I | Missense Mutation (SNP) | VAF 57/587 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.107); called by muse, mutect2
- ANKRD54 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 30/434 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2
- ANKRD61 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 43/788 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKUB1 | c.234+1G>A p.X78_splice | Splice Site (SNP) | VAF 40/354 reads (11%) | called by muse, mutect2
- AP1M1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- APOB | c.12713G>A p.G4238D | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.544); called by muse, mutect2
- APOL3 | c.596G>A p.G199D (on ENST00000349314 / NM_145640.2; = p.G128D on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/632 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARAP1 | c.3532G>A p.V1178M (on ENST00000393609 / NM_001040118.2; = p.V933M on NM_015242.4) | Missense Mutation (SNP) | VAF 18/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ARHGAP31 | c.349-1G>A p.X117_splice | Splice Site (SNP) | VAF 21/382 reads (5%) | called by muse, mutect2
- ARHGAP4 | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- ARHGAP5 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 16/379 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- ARHGEF15 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 48/613 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- ARID1A | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 74/868 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.132); called by muse, mutect2
- ARID2 | c.2407G>A p.G803S | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARID4B | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ASXL3 | c.4417G>A p.V1473I | Missense Mutation (SNP) | VAF 27/568 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ATG7 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 56/618 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP13A2 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 24/792 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- ATP2B1 | c.1830G>A p.K610= | Splice Region (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- ATP6V0A2 | c.1517A>G p.D506G | Missense Mutation (SNP) | VAF 20/505 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- ATXN7L1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 54/870 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- AZI2 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 33/415 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.36); called by muse, mutect2
- BBOF1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- BCAT2 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 32/644 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL11A | c.1742G>T p.G581V (on ENST00000335712 / NM_001365609.1; = p.G615V on NM_018014.4) | Missense Mutation (SNP) | VAF 33/749 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- BHLHA15 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 21/668 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2
- BOLL | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- BTAF1 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2
- BTN1A1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- C16orf71 | c.1292G>A p.G431E | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2
- C20orf96 | c.44C>T p.S15F (on ENST00000360321 / NM_153269.3; = p.S14F on NM_080571.1) | Missense Mutation (SNP) | VAF 23/569 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.095); called by muse, mutect2
- C2CD6 | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 22/485 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.273); called by muse, mutect2
- C2orf81 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 26/762 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2
- C6orf58 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 35/570 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2
- CACNA1F | c.4238G>A p.G1413D | Missense Mutation (SNP) | VAF 70/417 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARMIL3 | c.1629C>T p.S543= | Splice Region (SNP) | VAF 32/462 reads (7%) | called by muse, mutect2
- CCDC102B | c.892A>C p.K298Q | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CCDC114 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 57/650 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); called by muse, mutect2
- CCDC114 | c.372G>A p.R124= | Splice Region (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- CCZ1 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- CDC42EP1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 69/625 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH18 | c.2204T>G p.L735R | Missense Mutation (SNP) | VAF 25/607 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDK19 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 89/729 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CELA3B | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CERS3 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 41/393 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP61 | c.3368T>C p.L1123P | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- CHAMP1 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 68/732 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.157); called by muse, mutect2
- CHD4 | c.3682G>A p.G1228R (on ENST00000357008 / NM_001363606.2; = p.G1241R on NM_001273.5) | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.965); called by muse, mutect2
- CHD6 | c.2939A>G p.D980G | Missense Mutation (SNP) | VAF 91/535 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHD7 | c.6413G>A p.G2138D | Missense Mutation (SNP) | VAF 24/483 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- CHD8 | c.2777C>T p.T926I (on ENST00000646647 / NM_001170629.2; = p.T647I on NM_020920.4) | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHFR | c.760G>A p.E254K (on ENST00000432561 / NM_001161345.1; = p.E213K on NM_018223.2) | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); called by muse, mutect2
- CHODL | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- CIC | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 23/771 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- CIR1 | c.72+1G>A p.X24_splice | Splice Site (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- CLCN4 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- CLP1 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 27/578 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- CMTM1 | c.241G>A p.D81N (on ENST00000457188 / NM_181269.3; = p.D198N on NM_052999.4) | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNST | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 29/508 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2
- COL7A1 | c.1041G>A p.W347* | Nonsense Mutation (SNP) | VAF 44/603 reads (7%) | called by muse, mutect2
- CPOX | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 156/917 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CTTNBP2 | c.4421G>A p.W1474* | Nonsense Mutation (SNP) | VAF 54/599 reads (9%) | called by muse, mutect2
- CTTNBP2 | c.3346C>T p.L1116= | Splice Region (SNP) | VAF 18/461 reads (4%) | called by muse, mutect2
- CXCL12 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.616); called by muse, mutect2
- CYP3A5 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 35/461 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- DARS2 | c.1917_1927del p.K640Sfs*12 | Frame Shift Del (DEL) | VAF 32/291 reads (11%) | called by mutect2, pindel, varscan2
- DCAF12L2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 16/583 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- DHPS | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 50/536 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- DHRS11 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 52/971 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2
- DICER1 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.276); called by muse, mutect2
- DIP2C | c.2907C>T p.F969= | Splice Region (SNP) | VAF 25/506 reads (5%) | called by muse, mutect2
- DIRAS1 | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 62/756 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); called by muse, mutect2
- DNAJC6 | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 44/574 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- DOCK11 | c.1177-1G>A p.X393_splice | Splice Site (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- DOCK3 | c.3121G>A p.V1041I | Missense Mutation (SNP) | VAF 19/515 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2
- DSG3 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 25/520 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DYNC2H1 | c.8458C>T p.P2820S | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2
- DZANK1 | c.298T>C p.F100L | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EBF4 | c.1541-1G>A p.X514_splice (on ENST00000609451; = p.X510_splice on NM_001110514.1) | Splice Site (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- ECPAS | c.3497C>T p.T1166I | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- EEA1 | c.3553G>A p.A1185T | Missense Mutation (SNP) | VAF 36/646 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- EIF2AK4 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 26/427 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ELFN1 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 35/1322 reads (3%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.019); called by muse, mutect2
- ERCC3 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 20/671 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ERMAP | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 23/558 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ERVMER34-1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 50/536 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- ESCO1 | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- ESF1 | c.2102T>G p.I701R | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FAM126A | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 71/513 reads (14%) | called by muse, mutect2, varscan2
- FAM221A | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 19/533 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2
- FAM47A | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.124); called by muse, mutect2
- FAM83F | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 24/475 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- FAP | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FARSB | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 13/434 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2
- FASN | c.4532G>A p.W1511* | Nonsense Mutation (SNP) | VAF 38/734 reads (5%) | called by muse, mutect2
- FAT1 | c.4283C>T p.T1428I | Missense Mutation (SNP) | VAF 34/539 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- FBN3 | c.351G>A p.G117= | Splice Region (SNP) | VAF 24/352 reads (7%) | called by muse, mutect2
- FBXL18 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 60/847 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2
- FCER2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 50/648 reads (8%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- FER1L6 | c.3224C>T p.T1075I | Missense Mutation (SNP) | VAF 20/614 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- FGF10 | c.325+1G>T p.X109_splice | Splice Site (SNP) | VAF 38/258 reads (15%) | called by muse, varscan2
- FHOD3 | c.2357A>G p.Y786C (on ENST00000359247 / NM_001281739.3; = p.Y803C on NM_025135.5) | Missense Mutation (SNP) | VAF 85/502 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FNBP4 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- FNDC1 | c.5557C>T p.P1853S | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FOXJ1 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 30/878 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.065); called by muse, mutect2
- FRMPD2 | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.17731A>G p.T5911A | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2
- FUNDC2 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FYTTD1 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 13/389 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.144); called by muse, mutect2
- GAS2L1 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 84/939 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.246); called by muse, mutect2
- GCC1 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 32/1028 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2
- GCC2 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2
- GIT2 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 19/531 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2
- GLB1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- GLYATL1 | c.814G>A p.D272N (on ENST00000317391 / NM_001354699.1; = p.D303N on NM_080661.4) | Missense Mutation (SNP) | VAF 25/566 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2
- GMNC | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2
- GOLGA4 | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 37/434 reads (9%) | called by muse, mutect2
- GPR173 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- GPR85 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 93/582 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GSAP | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 22/507 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- GSG1 | c.481G>A p.E161K (on ENST00000651961 / NM_001080555.4; = p.G125S on NM_031289.5) | Missense Mutation (SNP) | VAF 53/606 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2
- HCFC1 | c.4613C>T p.S1538F | Missense Mutation (SNP) | VAF 27/504 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- HECW1 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 29/673 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2
- HECW2 | c.2200G>A p.G734R | Missense Mutation (SNP) | VAF 24/912 reads (3%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.365); called by muse, mutect2
- HEPH | c.3116C>T p.P1039L (on ENST00000343002; = p.P772L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- HIC1 | c.863C>T p.S288L (on ENST00000322941 / NM_001098202.1; = p.S269L on NM_006497.4) | Missense Mutation (SNP) | VAF 60/974 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- HLA-DPA1 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 35/1025 reads (3%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.573); called by muse, mutect2
- HMCN1 | c.1109G>A p.S370N | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- HS6ST3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 39/567 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2
- HSD3B7 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 41/558 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2
- IARS1 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- IGSF3 | c.3266C>T p.P1089L (on ENST00000369486 / NM_001007237.3; = p.P1109L on NM_001542.4) | Missense Mutation (SNP) | VAF 22/559 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); called by muse, mutect2
- IL11RA | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 60/685 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); called by muse, mutect2
- IL1R1 | c.1550G>A p.G517E | Missense Mutation (SNP) | VAF 23/626 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- IL27RA | c.1694G>A p.S565N | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IPO9 | c.1470G>A p.V490= | Splice Region (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- IRX1 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 45/702 reads (6%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.928); called by muse, mutect2
- JAK2 | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- JUN | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 38/980 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KAT5 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 44/618 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCTD10 | c.745A>T p.I249F | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- KDM4F | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 18/593 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM5A | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2
- KIAA1522 | c.2107G>A p.E703K (on ENST00000373480 / NM_001198972.2; = p.E762K on NM_020888.3) | Missense Mutation (SNP) | VAF 24/480 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2
- KLF18 | c.2885G>A p.R962K | Missense Mutation (SNP) | VAF 27/416 reads (6%) | SIFT tolerated (1); called by muse, mutect2
- KLHL24 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); called by muse, mutect2
- KLHL9 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 61/615 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KMT2E | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRT27 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 24/633 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2
- LARP1B | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 31/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- LCTL | c.494_497del p.K165Tfs*7 | Frame Shift Del (DEL) | VAF 51/342 reads (15%) | called by mutect2, pindel, varscan2
- LDLRAD1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); called by muse, mutect2
- LEF1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- LRCH3 | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- LRFN5 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 34/584 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- LRP8 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 24/640 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LYAR | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2
- MACF1 | c.10060G>A p.E3354K | Missense Mutation (SNP) | VAF 23/409 reads (6%) | called by muse, mutect2
- MAGI2 | c.3457G>A p.G1153R | Missense Mutation (SNP) | VAF 30/677 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- MAP1B | c.5560C>T p.P1854S | Missense Mutation (SNP) | VAF 54/538 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MAP3K1 | c.1364G>A p.S455N | Missense Mutation (SNP) | VAF 48/560 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAP3K10 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 23/795 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- MAPK8IP2 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 78/874 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MARF1 | c.5089C>T p.P1697S | Missense Mutation (SNP) | VAF 19/694 reads (3%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.026); called by muse, mutect2
- MDN1 | c.15825+1G>A p.X5275_splice | Splice Site (SNP) | VAF 24/245 reads (10%) | called by muse, mutect2, varscan2
- MEIS1 | c.13-1G>A p.X5_splice | Splice Site (SNP) | VAF 28/367 reads (8%) | called by muse, mutect2
- MEST | c.27-1G>A p.X9_splice | Splice Site (SNP) | VAF 20/482 reads (4%) | called by muse, mutect2
- MGAT4A | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 24/754 reads (3%) | called by muse, mutect2
- MIB2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 67/873 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.281); called by muse, mutect2
- MIB2 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 47/1035 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- MORC2 | c.1474G>A p.E492K (on ENST00000397641 / NM_001303256.3; = p.E430K on NM_014941.3) | Missense Mutation (SNP) | VAF 20/492 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2
- MORN5 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- MPDZ | c.5170C>T p.L1724F | Missense Mutation (SNP) | VAF 42/616 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MRPS18B | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 38/894 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MSC | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 41/488 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- MTFR1L | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2
- MTRNR2L11 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- MUC17 | c.9242C>T p.T3081I | Missense Mutation (SNP) | VAF 24/899 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); called by muse, mutect2
- MUC5B | c.7541C>T p.S2514F | Missense Mutation (SNP) | VAF 34/756 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- MUC5B | c.9128C>T p.S3043F | Missense Mutation (SNP) | VAF 89/1046 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2
- MUL1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 27/564 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by muse, mutect2
- MUSK | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 38/449 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2
- MYOM1 | c.2276G>A p.W759* | Nonsense Mutation (SNP) | VAF 35/488 reads (7%) | called by muse, mutect2
- MYRF | c.2716C>T p.P906S (on ENST00000278836 / NM_001127392.3; = p.P871S on NM_013279.4) | Missense Mutation (SNP) | VAF 33/658 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- NAT16 | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 44/1322 reads (3%) | called by muse, mutect2
- NBEA | c.6607C>T p.L2203F | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- NEFL | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 113/644 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- NF1 | c.7131del p.F2377Lfs*19 (on ENST00000358273 / NM_001042492.3; = p.F2356Lfs*19 on NM_000267.3) | Frame Shift Del (DEL) | VAF 64/474 reads (14%) | called by mutect2, pindel, varscan2
- NFX1 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 55/477 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKIRAS2 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 20/532 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2
- NLRP7 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 38/953 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.165); called by muse, mutect2
- NMU | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- NOTCH4 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 32/1040 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2
- NR0B2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 62/658 reads (9%) | called by muse, mutect2
- NSMF | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 104/1226 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- NUMA1 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2
- NUP160 | c.4066G>C p.E1356Q | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NUPR1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); called by muse, mutect2
- NWD1 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2
- OMA1 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.199); called by muse, mutect2
- OPA1 | c.817C>T p.L273F (on ENST00000361510 / NM_130837.3; = p.L218F on NM_015560.3) | Missense Mutation (SNP) | VAF 17/417 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- OPHN1 | c.2324+1G>A p.X775_splice | Splice Site (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- OR1L6 | c.426G>A p.M142I (on ENST00000373684; = p.M106I on NM_001004453.2) | Missense Mutation (SNP) | VAF 18/600 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR4Q2 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- OR6J1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- OR8K3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 73/780 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); called by muse, mutect2
- OSBPL10 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.219); called by muse, mutect2
- OVCH2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.315); called by muse, mutect2
- OVGP1 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 18/652 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2
- PARP10 | c.2552_2553del p.V851Afs*15 | Frame Shift Del (DEL) | VAF 67/458 reads (15%) | called by mutect2, pindel, varscan2
- PARVB | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 38/395 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- PBX2 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 31/909 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCBP4 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 44/619 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB4 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 39/624 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- PDCD1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 76/907 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- PGGHG | c.1757C>T p.T586I | Missense Mutation (SNP) | VAF 36/756 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PID1 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 38/406 reads (9%) | PolyPhen benign (0); called by muse, mutect2
- PIEZO2 | c.5862G>A p.M1954I | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PIMREG | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PLAAT5 | c.371_375+5del p.X124_splice | Splice Site (DEL) | VAF 26/193 reads (13%) | called by mutect2, pindel, varscan2
- PLCD3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 24/756 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.494); called by muse, mutect2
- PLEKHM2 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 54/617 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLVAP | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 22/612 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); called by muse, mutect2
- PPM1K | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 32/552 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PPP1R12A | c.2649+1G>A p.X883_splice | Splice Site (SNP) | VAF 20/299 reads (7%) | called by muse, mutect2
- PPP1R14C | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPP2R2D | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRICKLE3 | c.1804G>A p.G602R | Missense Mutation (SNP) | VAF 25/446 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2
- PRMT6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 65/573 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROX1 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 38/663 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRSS55 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- PSMD12 | c.1246del p.Q416Rfs*10 | Frame Shift Del (DEL) | VAF 67/421 reads (16%) | called by mutect2, pindel, varscan2
- PTPN11 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.076); called by muse, mutect2
- PTPRF | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 27/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRZ1 | c.2264G>A p.G755D | Missense Mutation (SNP) | VAF 55/748 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRZ1 | c.6373C>T p.Q2125* | Nonsense Mutation (SNP) | VAF 29/251 reads (12%) | called by muse, mutect2, varscan2
- RAB3B | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 41/515 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2
- RBM42 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 56/682 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2
- REPS2 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- REV3L | c.5150G>A p.W1717* | Nonsense Mutation (SNP) | VAF 39/462 reads (8%) | called by muse, mutect2
- RFX7 | c.1751C>T p.S584L (on ENST00000559447 / NM_001368074.1; = p.S681L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/522 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.039); called by muse, mutect2
- RGL3 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 29/494 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- RHOB | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 65/652 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RLN1 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.25); called by muse, mutect2
- RNF150 | c.842G>A p.C281Y | Missense Mutation (SNP) | VAF 89/421 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF43 | c.2075G>A p.W692* | Nonsense Mutation (SNP) | VAF 22/746 reads (3%) | called by muse, mutect2
- RPL19 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2
- RPS6KA5 | c.1232G>A p.S411N | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- SALL2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 24/491 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- SCAF4 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 48/519 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- SCG3 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2
- SCUBE1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SECISBP2L | c.206del p.Q69Rfs*43 | Frame Shift Del (DEL) | VAF 33/202 reads (16%) | called by mutect2, pindel*, varscan2
- SELENOW | c.54G>A p.K18= | Splice Region (SNP) | VAF 25/515 reads (5%) | called by muse, mutect2
- SENP2 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 20/568 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2
- SETD1A | c.1550G>A p.S517N | Missense Mutation (SNP) | VAF 26/722 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- SETD1B | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 23/865 reads (3%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.858); called by muse, mutect2
- SFSWAP | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 64/584 reads (11%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGPL1 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2
- SH3KBP1 | c.801G>A p.K267= | Splice Region (SNP) | VAF 37/190 reads (19%) | called by muse, mutect2, varscan2
- SHBG | c.204-1G>A p.X68_splice | Splice Site (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- SKI | c.1998G>A p.Q666= | Splice Region (SNP) | VAF 58/622 reads (9%) | called by muse, mutect2
- SLC16A13 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 31/635 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.348); called by muse, mutect2
- SLC22A10 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 51/518 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2
- SLC22A15 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 25/322 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.342); called by muse, mutect2
- SLC22A7 | c.805G>A p.A269T (on ENST00000372585 / NM_153320.2; = p.A267T on NM_006672.3) | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2
- SLC4A5 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 25/431 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC6A4 | c.837+1G>A p.X279_splice | Splice Site (SNP) | VAF 13/299 reads (4%) | called by muse, mutect2
- SLC7A1 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 30/573 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.02); called by muse, mutect2
- SLC9A2 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLIT3 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 20/449 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.158); called by muse, mutect2
- SMYD2 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNRNP200 | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2
- SNTA1 | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 65/384 reads (17%) | called by muse, mutect2, varscan2
- SORBS1 | c.1031C>T p.T344I (on ENST00000361941 / NM_001034954.2; = p.T180I on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.284); called by muse, mutect2
- SOX18 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 32/642 reads (5%) | called by muse, mutect2
- SP3 | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPAG16 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 68/786 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPPL2C | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 30/1226 reads (2%) | SIFT tolerated (0.23); PolyPhen benign (0.309); called by muse, mutect2
- SPPL2C | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 98/925 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRY3 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 69/1102 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- SREBF1 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 54/1050 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- SRGAP3 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 64/812 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.142); called by muse, mutect2
- ST8SIA1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STAG3 | c.3134C>T p.P1045L | Missense Mutation (SNP) | VAF 27/804 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- STARD6 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYN1 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.081); called by muse, mutect2
- SYNE1 | c.5100+5G>A | Splice Region (SNP) | VAF 45/652 reads (7%) | called by muse, mutect2
- SYP | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 88/507 reads (17%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- TASOR2 | c.6328C>G p.L2110V | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TBXAS1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 58/644 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2
- TENM3 | c.5999T>C p.I2000T | Missense Mutation (SNP) | VAF 25/701 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- TET3 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 34/770 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2
- TFAP2E | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 31/697 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- TFDP2 | c.186G>A p.M62I (on ENST00000489671 / NM_001178139.2; = p.M1? on NM_006286.5) | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2
- TFRC | c.2252G>A p.G751D | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TJP2 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- TLL2 | c.1944G>A p.W648* | Nonsense Mutation (SNP) | VAF 46/502 reads (9%) | called by muse, mutect2
- TMCC3 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 23/686 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- TMEM109 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 39/319 reads (12%) | called by muse, mutect2, varscan2
- TMEM176A | c.644G>A p.W215* | Nonsense Mutation (SNP) | VAF 27/537 reads (5%) | called by muse, mutect2
- TMEM209 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 22/613 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2
- TMTC2 | c.1919T>A p.F640Y | Missense Mutation (SNP) | VAF 17/393 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- TNIK | c.1205G>A p.R402K | Missense Mutation (SNP) | VAF 26/644 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2
- TNNT3 | c.773C>T p.T258I (on ENST00000397301 / NM_001367846.1; = p.T247I on NM_006757.4) | Missense Mutation (SNP) | VAF 46/541 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.266); called by muse, mutect2
- TNRC6C | c.2539C>T p.H847Y | Missense Mutation (SNP) | VAF 54/584 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.173); called by muse, mutect2
- TNXB | c.8036C>T p.T2679I (on ENST00000647633; = p.T2432I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/1008 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TOGARAM1 | c.4430G>A p.R1477K | Missense Mutation (SNP) | VAF 53/289 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TOMM34 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 43/542 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAF3 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 53/621 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRAF3IP1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 19/435 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.212); called by muse, mutect2
- TRAF6 | c.1409G>A p.G470D | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM15 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 24/730 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- TRIM26 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 30/994 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); called by muse, mutect2
- TRIP12 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TRPA1 | c.2426G>A p.W809* | Nonsense Mutation (SNP) | VAF 77/417 reads (18%) | called by muse, mutect2, varscan2
- TRPA1 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2
- TRPV6 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- TRRAP | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 62/464 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSLP | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 29/497 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- TTC33 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 60/591 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC6 | c.1022T>C p.F341S | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.074); called by muse, mutect2
- TTLL5 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2
- TTLL7 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); called by muse, mutect2
- TTN | c.87949G>A p.V29317M (on ENST00000591111; = p.V21893M on NM_003319.4) | Missense Mutation (SNP) | VAF 18/370 reads (5%) | PolyPhen benign (0.366); called by muse, mutect2
- TTN | c.53174G>A p.G17725E (on ENST00000591111; = p.G10301E on NM_003319.4) | Missense Mutation (SNP) | VAF 20/653 reads (3%) | PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.32968G>A p.V10990M (on ENST00000591111; = p.V10063M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/426 reads (4%) | PolyPhen benign (0.299); called by muse, mutect2
- TUBA8 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 58/515 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- TUBB2A | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 26/720 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.516); called by muse, mutect2
- TULP4 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 61/510 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBE4B | c.2156C>T p.T719I (on ENST00000343090 / NM_001105562.3; = p.T590I on NM_006048.5) | Missense Mutation (SNP) | VAF 44/604 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.091); called by muse, mutect2
- USF3 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 28/611 reads (5%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); called by muse, mutect2
- USH1C | c.1380+1G>A p.X460_splice | Splice Site (SNP) | VAF 45/416 reads (11%) | called by muse, mutect2, varscan2
- USP24 | c.4139G>A p.G1380E | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.29); called by muse, mutect2
- USP9X | c.1393C>T p.L465F | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- VPS13A | c.3960G>A p.E1320= | Splice Region (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- VPS13B | c.7264T>C p.S2422P | Missense Mutation (SNP) | VAF 43/464 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- WASL | c.117+1G>A p.X39_splice | Splice Site (SNP) | VAF 20/466 reads (4%) | called by muse, mutect2
- WDR11 | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, mutect2
- WDR19 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- WDR76 | c.1075dup p.H359Pfs*2 | Frame Shift Ins (INS) | VAF 62/471 reads (13%) | called by mutect2, pindel, varscan2
- WDTC1 | c.1909G>A p.A637T (on ENST00000319394 / NM_001276252.2; = p.A636T on NM_015023.5) | Missense Mutation (SNP) | VAF 29/680 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2
- WIPF2 | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- WWC1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 24/638 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- XPO7 | c.1104G>A p.Q368= | Splice Region (SNP) | VAF 21/286 reads (7%) | called by muse, mutect2
- YEATS2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 19/502 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- YTHDF2 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 36/702 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- YTHDF3 | c.837G>A p.W279* | Nonsense Mutation (SNP) | VAF 43/584 reads (7%) | called by muse, mutect2
- Z83844.2 | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 19/623 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZBED4 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 25/696 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB4 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 145/754 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, varscan2
- ZDHHC13 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 20/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFPM1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 74/762 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2
- ZMYND8 | c.1102C>T p.P368S (on ENST00000311275 / NM_001363741.2; = p.P388S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/546 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNF185 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ZNF227 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 22/564 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- ZNF227 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF236 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 22/748 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF266 | c.437G>A p.C146Y | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF268 | c.2348G>A p.S783N | Missense Mutation (SNP) | VAF 25/659 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- ZNF335 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 26/648 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2
- ZNF516 | c.2080_2089delinsGT p.P694Vfs*47 | Frame Shift Del (DEL) | VAF 83/569 reads (15%) | called by pindel, varscan2*
- ZNF527 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
- ZNF587 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- ZNF589 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF638 | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 55/463 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF793 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- ABCA5 | c.2952G>A p.V984= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- ABCB4 | c.3741C>T p.D1247= (on ENST00000265723 / NM_018849.3; = p.D1240= on NM_000443.4) | Silent (SNP) | VAF 54/881 reads (6%) | called by muse, mutect2
- ABHD3 | c.996G>A p.K332= | Silent (SNP) | VAF 28/391 reads (7%) | called by muse, mutect2
- ABR | c.453G>A p.K151= (on ENST00000302538 / NM_021962.5; = p.K114= on NM_001092.5) | Silent (SNP) | VAF 138/774 reads (18%) | called by muse, mutect2, varscan2
- ACE | c.1239C>T p.N413= | Silent (SNP) | VAF 69/659 reads (10%) | catalogued as COSV52005129; called by muse, mutect2
- ACOT4 | c.915C>T p.N305= | Silent (SNP) | VAF 55/559 reads (10%) | called by muse, mutect2
- ADAMTS1 | c.2118C>T p.D706= | Silent (SNP) | VAF 53/609 reads (9%) | catalogued as rs773568395; called by muse, mutect2
- ADCYAP1R1 | c.960C>T p.N320= | Silent (SNP) | VAF 26/455 reads (6%) | called by muse, mutect2
- ADGRG6 | c.1401G>A p.K467= | Silent (SNP) | VAF 66/369 reads (18%) | called by muse, mutect2, varscan2
- ADH1B | c.1098G>A p.G366= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV59298214; called by muse, mutect2, varscan2
- AHCTF1 | c.3099C>T p.D1033= (on ENST00000366508; = p.D1007= on NM_015446.5) | Silent (SNP) | VAF 21/515 reads (4%) | catalogued as COSV100404631; called by muse, mutect2
- AKR1A1 | c.319C>T p.L107= | Silent (SNP) | VAF 34/617 reads (6%) | catalogued as COSV100698709; called by muse, mutect2
- AKR1B15 | c.300C>T p.D100= | Silent (SNP) | VAF 25/578 reads (4%) | called by muse, mutect2
- ALS2CL | c.549G>A p.R183= | Silent (SNP) | VAF 31/434 reads (7%) | called by muse, mutect2
- ANO7 | c.2196C>T p.A732= (on ENST00000274979; = p.A678= on NM_001370694.2) | Silent (SNP) | VAF 54/958 reads (6%) | called by muse, mutect2
- ANPEP | c.837G>A p.L279= | Silent (SNP) | VAF 22/690 reads (3%) | catalogued as COSV55589630; called by muse, mutect2
- AP3M2 | c.229C>T p.L77= | Silent (SNP) | VAF 76/391 reads (19%) | catalogued as COSV51530324; called by muse, mutect2, varscan2
- APC2 | c.2655G>A p.R885= | Silent (SNP) | VAF 166/823 reads (20%) | catalogued as rs758239892; called by muse, mutect2, varscan2
- ARL10 | c.135C>T p.A45= | Silent (SNP) | VAF 70/690 reads (10%) | called by muse, mutect2, varscan2
- ARMC4 | c.2118C>T p.T706= | Silent (SNP) | VAF 33/294 reads (11%) | called by muse, mutect2, varscan2
- ASB10 | c.915C>A p.G305= (on ENST00000420175 / NM_001142459.2; = p.G290= on NM_080871.4) | Silent (SNP) | VAF 120/763 reads (16%) | catalogued as COSV51999183; called by muse, mutect2, varscan2
- ATAT1 | c.891C>T p.L297= | Silent (SNP) | VAF 71/766 reads (9%) | called by muse, mutect2
- ATF7IP | c.138C>T p.G46= | Silent (SNP) | VAF 38/480 reads (8%) | called by muse, mutect2
- ATP9B | c.189G>A p.E63= | Silent (SNP) | VAF 38/549 reads (7%) | catalogued as rs1177860049, COSV100303270; called by muse, mutect2
- ATRN | c.1089C>T p.H363= | Silent (SNP) | VAF 25/367 reads (7%) | catalogued as rs1568723176; called by muse, mutect2
- ATRN | c.2316G>A p.Q772= | Silent (SNP) | VAF 24/548 reads (4%) | called by muse, mutect2
- AVPR1B | c.678C>T p.I226= | Silent (SNP) | VAF 34/337 reads (10%) | called by muse, mutect2, varscan2
- B3GALT4 | c.960C>T p.D320= | Silent (SNP) | VAF 93/1088 reads (9%) | called by muse, mutect2
- B4GALT2 | c.939C>T p.R313= | Silent (SNP) | VAF 37/554 reads (7%) | catalogued as rs746554871, COSV58846340; called by muse, mutect2
- BANK1 | c.2220C>T p.L740= | Silent (SNP) | VAF 37/364 reads (10%) | called by muse, mutect2, varscan2
- BCO2 | c.1665C>T p.N555= | Silent (SNP) | VAF 25/416 reads (6%) | called by muse, mutect2
- BEST2 | c.1338C>T p.C446= | Silent (SNP) | VAF 31/1096 reads (3%) | catalogued as rs1202899641; called by muse, mutect2
- BNC1 | c.2283C>T p.S761= | Silent (SNP) | VAF 20/469 reads (4%) | catalogued as rs926112222; called by muse, mutect2
- BOC | c.1644G>A p.E548= | Silent (SNP) | VAF 19/511 reads (4%) | called by muse, mutect2
- CACNA1G | c.3669C>T p.D1223= | Silent (SNP) | VAF 53/488 reads (11%) | catalogued as rs372686733; called by muse, mutect2, varscan2
- CACNA1H | c.4662G>A p.V1554= | Silent (SNP) | VAF 56/782 reads (7%) | catalogued as COSV62001892; called by muse, mutect2
- CALCA | c.252G>A p.R84= | Silent (SNP) | VAF 13/390 reads (3%) | called by muse, mutect2
- CAMKK1 | c.873C>T p.I291= | Silent (SNP) | VAF 32/699 reads (5%) | catalogued as rs960048193; called by muse, mutect2
- CAPN14 | c.181C>T p.L61= | Silent (SNP) | VAF 64/774 reads (8%) | called by muse, mutect2
- CBX5 | c.76C>T p.L26= | Silent (SNP) | VAF 62/788 reads (8%) | called by muse, mutect2
- CCDC136 | c.2403G>A p.G801= | Silent (SNP) | VAF 30/892 reads (3%) | called by muse, mutect2
- CCDC60 | c.1272C>T p.V424= | Silent (SNP) | VAF 30/388 reads (8%) | called by muse, mutect2
- CD69 | c.264C>T p.D88= | Silent (SNP) | VAF 28/636 reads (4%) | called by muse, mutect2
- CFAP92 | c.2061C>T p.A687= | Silent (SNP) | VAF 74/505 reads (15%) | called by muse, mutect2, varscan2
- CHRNA6 | c.208C>T p.L70= | Silent (SNP) | VAF 35/405 reads (9%) | catalogued as rs757220335; called by muse, mutect2
- CLASP1 | c.1587G>A p.E529= | Silent (SNP) | VAF 30/616 reads (5%) | called by muse, mutect2
- CLIP1 | c.1824G>A p.K608= (on ENST00000620786 / NM_001247997.1; = p.K597= on NM_002956.2) | Silent (SNP) | VAF 21/654 reads (3%) | called by muse, mutect2
- CNOT6L | c.1566C>T p.H522= (on ENST00000504123 / NM_001286790.2; = p.H517= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/568 reads (4%) | called by muse, mutect2
- CNTNAP5 | c.2547C>T p.T849= | Silent (SNP) | VAF 23/432 reads (5%) | called by muse, mutect2
- COL6A3 | c.7248C>T p.D2416= | Silent (SNP) | VAF 19/587 reads (3%) | called by muse, mutect2
- COMMD3-BMI1 | c.330C>T p.S110= | Silent (SNP) | VAF 18/241 reads (7%) | catalogued as COSV64958846; called by muse, mutect2
- COPG1 | c.1740C>T p.P580= | Silent (SNP) | VAF 57/395 reads (14%) | called by muse, mutect2, varscan2
- CREB5 | c.1494C>T p.T498= (on ENST00000357727 / NM_182898.4; = p.T491= on NM_004904.3) | Silent (SNP) | VAF 40/618 reads (6%) | called by muse, mutect2
- CTDP1 | c.102G>A p.E34= | Silent (SNP) | VAF 36/996 reads (4%) | catalogued as rs1308297464; called by muse, mutect2
- CTSO | c.129C>T p.A43= | Silent (SNP) | VAF 19/542 reads (4%) | called by muse, mutect2
- CYBB | c.18G>A p.V6= | Silent (SNP) | VAF 41/283 reads (14%) | called by muse, mutect2, varscan2
- DCAF1 | c.1320T>C p.D440= | Silent (SNP) | VAF 17/367 reads (5%) | catalogued as rs1553635216; called by muse, mutect2
- DCAF4L1 | c.630G>A p.L210= | Silent (SNP) | VAF 41/520 reads (8%) | called by muse, mutect2
- DCHS1 | c.9351A>C p.T3117= | Silent (SNP) | VAF 21/729 reads (3%) | called by muse, mutect2
- DCHS1 | c.6237G>A p.E2079= | Silent (SNP) | VAF 23/456 reads (5%) | called by muse, mutect2
- DDX5 | c.1731C>T p.Y577= | Silent (SNP) | VAF 26/636 reads (4%) | catalogued as rs201627861; called by muse, mutect2
- DECR2 | c.6C>T p.A2= | Silent (SNP) | VAF 89/521 reads (17%) | catalogued as rs771608292; called by muse, mutect2, varscan2
- DHX30 | c.2475C>T p.I825= (on ENST00000445061 / NM_138615.3; = p.I786= on NM_014966.3) | Silent (SNP) | VAF 52/415 reads (13%) | called by muse, mutect2, varscan2
- DLGAP1 | c.2784C>T p.I928= | Silent (SNP) | VAF 42/878 reads (5%) | called by muse, mutect2
- DNAH1 | c.7740C>T p.G2580= | Silent (SNP) | VAF 72/772 reads (9%) | called by muse, mutect2
- DNAH10 | c.1848C>T p.N616= (on ENST00000409039; = p.N555= on NM_207437.3) | Silent (SNP) | VAF 45/498 reads (9%) | called by muse, mutect2
- DNAH11 | c.2605T>C p.L869= | Silent (SNP) | VAF 107/578 reads (19%) | called by muse, mutect2, varscan2
- DNAH2 | c.5967G>A p.K1989= | Silent (SNP) | VAF 26/599 reads (4%) | called by muse, mutect2
- DNAJC3 | c.1278C>T p.F426= | Silent (SNP) | VAF 41/512 reads (8%) | called by muse, mutect2
- DNMT1 | c.2442G>A p.L814= | Silent (SNP) | VAF 43/691 reads (6%) | called by muse, mutect2
- DRD4 | c.804C>T p.G268= | Silent (SNP) | VAF 81/561 reads (14%) | called by muse, mutect2, varscan2
- DROSHA | c.3243T>C p.Y1081= | Silent (SNP) | VAF 19/497 reads (4%) | catalogued as rs1476258834; called by muse, mutect2
- DUS4L-BCAP29 | c.1527C>T p.N509= | Silent (SNP) | VAF 14/326 reads (4%) | called by muse, mutect2
- DYRK4 | c.546C>T p.T182= | Silent (SNP) | VAF 26/397 reads (7%) | catalogued as COSV50538236; called by muse, mutect2
- EAPP | c.27C>T p.D9= | Silent (SNP) | VAF 50/456 reads (11%) | called by muse, mutect2, varscan2
- EFCAB6 | c.2778G>A p.E926= | Silent (SNP) | VAF 24/611 reads (4%) | called by muse, mutect2
- EHD1 | c.318G>A p.E106= | Silent (SNP) | VAF 47/824 reads (6%) | called by muse, mutect2
- EHD4 | c.63G>A p.V21= | Silent (SNP) | VAF 73/872 reads (8%) | called by muse, mutect2
- EMILIN1 | c.825G>A p.R275= | Silent (SNP) | VAF 78/840 reads (9%) | catalogued as COSV99566506; called by muse, mutect2
- EML1 | c.2103C>T p.P701= | Silent (SNP) | VAF 26/269 reads (10%) | catalogued as COSV51744242; called by muse, mutect2, varscan2
- EOGT | c.1047A>G p.V349= | Silent (SNP) | VAF 23/495 reads (5%) | called by muse, mutect2
- EPHB4 | c.513G>A p.K171= | Silent (SNP) | VAF 50/830 reads (6%) | catalogued as rs1181413910; called by muse, mutect2
- EPPK1 | c.3558C>T p.T1186= | Silent (SNP) | VAF 72/881 reads (8%) | catalogued as rs1554660468; called by muse, mutect2
- ESPL1 | c.1983C>T p.D661= | Silent (SNP) | VAF 27/560 reads (5%) | catalogued as COSV57757535; called by muse, mutect2
- ESPL1 | c.4092G>A p.V1364= | Silent (SNP) | VAF 45/692 reads (7%) | catalogued as rs1314195229; called by muse, mutect2
- ETHE1 | c.252C>T p.H84= | Silent (SNP) | VAF 31/577 reads (5%) | called by muse, mutect2
- ETS2 | c.216C>T p.T72= | Silent (SNP) | VAF 20/474 reads (4%) | called by muse, mutect2
- EXD1 | c.346C>T p.L116= | Silent (SNP) | VAF 43/616 reads (7%) | catalogued as rs775607843; called by muse, mutect2
- EXOSC5 | c.90C>T p.H30= | Silent (SNP) | VAF 42/619 reads (7%) | called by muse, mutect2
- FAM171A1 | c.1942C>T p.L648= | Silent (SNP) | VAF 32/598 reads (5%) | called by muse, mutect2
- FAM207A | c.291G>A p.E97= | Silent (SNP) | VAF 26/456 reads (6%) | catalogued as COSV52419745; called by muse, mutect2
- FASN | c.3153T>C p.R1051= | Silent (SNP) | VAF 23/816 reads (3%) | catalogued as rs1259675098; called by muse, mutect2
- FAT1 | c.3837G>A p.K1279= | Silent (SNP) | VAF 26/603 reads (4%) | called by muse, mutect2
- FGF18 | c.282T>C p.G94= | Silent (SNP) | VAF 20/485 reads (4%) | called by muse, mutect2
- FHAD1 | c.4104G>A p.R1368= | Silent (SNP) | VAF 44/375 reads (12%) | called by muse, mutect2, varscan2
- FHOD3 | c.3258C>T p.I1086= (on ENST00000359247 / NM_001281739.3; = p.I1103= on NM_025135.5) | Silent (SNP) | VAF 32/378 reads (8%) | catalogued as COSV57163699; called by muse, mutect2
- FKRP | c.1113C>T p.D371= | Silent (SNP) | VAF 22/728 reads (3%) | catalogued as COSV100586674; called by muse, mutect2
- FOXI3 | c.324C>T p.P108= | Silent (SNP) | VAF 18/511 reads (4%) | called by muse, mutect2
- FOXK2 | c.474C>T p.S158= | Silent (SNP) | VAF 48/619 reads (8%) | called by muse, mutect2
- FREM3 | c.6258C>T p.I2086= | Silent (SNP) | VAF 42/548 reads (8%) | catalogued as rs189769405; called by muse, mutect2
- FYCO1 | c.1440G>A p.T480= | Silent (SNP) | VAF 71/679 reads (10%) | catalogued as COSV56120195; called by muse, mutect2, varscan2
- GCLC | c.66G>A p.G22= (on ENST00000643939; = p.G26= on NM_001498.4) | Silent (SNP) | VAF 58/575 reads (10%) | called by muse, mutect2, varscan2
- GFRA3 | c.663C>T p.A221= | Silent (SNP) | VAF 94/731 reads (13%) | catalogued as COSV51228284; called by muse, mutect2, varscan2
- GIT2 | c.1044C>T p.D348= (on ENST00000355312 / NM_057169.5; = p.D350= on NM_014776.5) | Silent (SNP) | VAF 23/545 reads (4%) | called by muse, mutect2
- GLTPD2 | c.345G>A p.L115= | Silent (SNP) | VAF 36/451 reads (8%) | called by muse, mutect2
- GPANK1 | c.879G>A p.Q293= | Silent (SNP) | VAF 72/1064 reads (7%) | called by muse, mutect2
- GPBP1 | c.378G>A p.K126= | Silent (SNP) | VAF 23/487 reads (5%) | catalogued as COSV53311885; called by muse, mutect2
- GRPEL1 | c.219G>A p.E73= | Silent (SNP) | VAF 16/352 reads (5%) | catalogued as rs1180781877; called by muse, mutect2
- GTPBP1 | c.1527C>T p.Y509= | Silent (SNP) | VAF 48/502 reads (10%) | catalogued as rs537370099; called by muse, mutect2
- H2AC1 | c.249C>T p.H83= | Silent (SNP) | VAF 33/649 reads (5%) | called by muse, mutect2
- HADH | c.171C>T p.D57= | Silent (SNP) | VAF 36/445 reads (8%) | catalogued as rs137853102, CM114217; called by muse, mutect2
- HDAC7 | c.1662G>A p.R554= (on ENST00000427332; = p.R593= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/676 reads (3%) | called by muse, mutect2
- HERC2 | c.2934C>T p.A978= | Silent (SNP) | VAF 65/752 reads (9%) | catalogued as COSV55319909; called by muse, mutect2
- HERPUD2 | c.93C>T p.N31= | Silent (SNP) | VAF 20/618 reads (3%) | called by muse, mutect2
- HHIPL2 | c.886C>T p.L296= | Silent (SNP) | VAF 27/433 reads (6%) | called by muse, mutect2
- HK2 | c.1155G>A p.L385= | Silent (SNP) | VAF 80/1036 reads (8%) | catalogued as rs1232009193; called by muse, mutect2
- HNRNPLL | c.1554C>T p.H518= | Silent (SNP) | VAF 14/347 reads (4%) | catalogued as rs974478719; called by muse, mutect2
- IGFBP4 | c.180C>T p.A60= | Silent (SNP) | VAF 76/982 reads (8%) | called by muse, mutect2
- IGSF3 | c.1467G>A p.V489= (on ENST00000369486 / NM_001007237.3; = p.V509= on NM_001542.4) | Silent (SNP) | VAF 67/610 reads (11%) | called by muse, mutect2, varscan2
- IKZF5 | c.969C>T p.N323= | Silent (SNP) | VAF 30/495 reads (6%) | called by muse, mutect2
- IL22RA1 | c.1041C>T p.S347= | Silent (SNP) | VAF 73/704 reads (10%) | catalogued as COSV54628456; called by muse, mutect2, varscan2
- IRX3 | c.336C>T p.H112= | Silent (SNP) | VAF 92/944 reads (10%) | catalogued as rs777467824; called by muse, mutect2
- ITGB5 | c.2259G>A p.E753= | Silent (SNP) | VAF 23/515 reads (4%) | catalogued as rs1001545116; called by muse, mutect2
- ITPR1 | c.5568C>T p.F1856= (on ENST00000354582; = p.F1801= on NM_002222.7) | Silent (SNP) | VAF 33/397 reads (8%) | catalogued as COSV56975702; called by muse, mutect2
- JMJD1C | c.4716G>A p.G1572= | Silent (SNP) | VAF 27/284 reads (10%) | catalogued as rs372195120; called by muse, mutect2
- KALRN | c.2550C>A p.I850= | Silent (SNP) | VAF 48/307 reads (16%) | called by muse, mutect2, varscan2
- KCNA4 | c.669G>A p.R223= | Silent (SNP) | VAF 46/518 reads (9%) | catalogued as rs201159519; called by muse, mutect2
- KCNA6 | c.879G>A p.R293= | Silent (SNP) | VAF 32/677 reads (5%) | called by muse, mutect2
- KCNH7 | c.2241G>A p.R747= | Silent (SNP) | VAF 28/559 reads (5%) | called by muse, mutect2
- KCNV1 | c.1479C>T p.S493= | Silent (SNP) | VAF 51/336 reads (15%) | catalogued as rs750819318, COSV52086625; called by muse, mutect2, varscan2
- KLB | c.2934G>A p.Q978= | Silent (SNP) | VAF 48/487 reads (10%) | called by muse, mutect2, varscan2
- KMT2B | c.2034G>A p.E678= | Silent (SNP) | VAF 24/700 reads (3%) | called by muse, mutect2
- KMT2D | c.10638G>A p.Q3546= | Silent (SNP) | VAF 78/516 reads (15%) | called by muse, mutect2, varscan2
- KPNB1 | c.681G>A p.Q227= | Silent (SNP) | VAF 38/466 reads (8%) | catalogued as rs1410815314, COSV51599691; called by muse, mutect2
- KRT3 | c.528C>T p.N176= | Silent (SNP) | VAF 54/614 reads (9%) | catalogued as rs1197536748; called by muse, mutect2
- LAMA1 | c.147C>T p.F49= | Silent (SNP) | VAF 62/631 reads (10%) | catalogued as COSV101057029; called by muse, mutect2
- LGMN | c.303G>A p.K101= | Silent (SNP) | VAF 20/531 reads (4%) | called by muse, mutect2
- LIMD1 | c.759C>T p.G253= | Silent (SNP) | VAF 21/657 reads (3%) | catalogued as rs1194569098; called by muse, mutect2
- LIPN | c.696C>T p.F232= | Silent (SNP) | VAF 23/258 reads (9%) | called by muse, mutect2
- LMO7 | c.3747A>G p.K1249= (on ENST00000357063; = p.K930= on NM_005358.5) | Silent (SNP) | VAF 44/445 reads (10%) | called by muse, mutect2
178 further variants in this file (0 protein-altering or splice-affecting, 150 silent, 28 other) are not listed here.
